Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A545, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A545-01A (Primary Tumor).

[page 1 of 2]
Gross Description: "Body and tail of pancreas, spleen." A 12.5 x 4.5 x 1.0 cm distal pancreas and a 74 gram, 9.5 x 5.5 x 2.9 cm unremarkable spleen. 2.1 cm from the pancreatic margin of resection, there is a well defined firm gray 2.5 x 2.0 x 1.0 cm mass. The pancreatic duct is grossly uninvolved. Remainder of the pancreatic tissue distally is firm and lobulated. Multiple lymph nodes are identified.

Microscopic Description: Specimen: Body/tail pancreas, spleen

Procedure: Distal pancreatectomy.

Tumor location: Body

Tumor size (greatest dimension): 2.5 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: Moderately to poorly differentiated

Microscopic tumor extension: Invades peripancreatic soft tissue

Surgical margins:

Proximal pancreas margin: Free of neoplasm by 21 mm

Angiolymphatic spread: Yes

Perineural spread: Yes, extensive

Treatment effect: No prior treatment

TNM Staging:

Tumor extent (pT3) Invasion beyond pancreas to peripancreatic soft tissue

Lymph nodes: pN1

Peripancreatic: 4 of 28 contain metastases

Other findings: Chronic pancreatitis. Ductal dysplasia (panIN types II and III)

AJCC Stage: IIB

Stage groupings: T3 N1 M0

Other findings/Comments: Unremarkable spleen.

100-0-3
adenocarcinoma, duct, NOS 8500/3
Site: pancreas, body C25.1

fw
11/20/12

[page 2 of 2]
Diagnosis Details: Pancreas: Invasive moderately to poorly differentiated adenocarcinoma with lymph node metastases

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Pancreatectomy and splenectomy

Tumor site: Pancreas gland

Tumor size: 2.5 x 2 x 1 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: Poorly to moderately differentiated

Tumor extent: Not specified

Lymph nodes: 4/28 positive for metastasis (Peripancreatic 4/28)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Reviewed (Initial):	11/19/12	

Source: NCI Genomic Data Commons file 0de84148-b9cf-4d1b-ab71-0be06c84b26b (TCGA-FB-A545.6DECAD9C-5059-4201-89EC-07F2062ED6A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).